Somatic mutation profile of tumor specimen MP2PRT-PAUJMU-TMP1-A (aliquot MP2PRT-PAUJMU-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUJMU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,204 days).
Specimen MP2PRT-PAUJMU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9baaa332-5b88-4e7a-80aa-c3daf4cb06e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJMU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJMU-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34684aa5-f4f0-44f7-8e9a-1a45660d02ef

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Splice Region 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 140/329 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 115/324 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EPPIN | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 185/425 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.108); catalogued as rs771546199; called by muse, mutect2, varscan2
- KIF4B | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 177/462 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775915028, COSV70528329; called by muse, mutect2, varscan2
- LRIG1 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs866817310, COSV56248974; called by muse, mutect2
- NRIP3 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 116/342 reads (34%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.877); catalogued as rs746688592, COSV58469024; called by muse, varscan2
- OBSCN | c.21188C>T p.P7063L | Missense Mutation (SNP) | VAF 239/618 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100803095; called by muse, mutect2, varscan2
- SIGLEC11 | c.1586G>T p.R529M | Missense Mutation (SNP) | VAF 195/495 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV70222171; called by muse, mutect2, varscan2
- TNP1 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 125/385 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.903); catalogued as rs531889646, COSV52696413; called by muse, mutect2, varscan2
- WFIKKN1 | c.960C>A p.D320E | Missense Mutation (SNP) | VAF 107/582 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.604); catalogued as COSV50193145; called by muse, mutect2, varscan2
- DGKQ | c.888G>A p.G296= | Splice Region (SNP) | VAF 191/694 reads (28%) | called by muse, mutect2, varscan2
- KCNB1 | c.27C>T p.G9= | Silent (SNP) | VAF 146/378 reads (39%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.1943-366C>T | Intron (SNP) | VAF 228/608 reads (38%) | called by muse, mutect2, varscan2
